Somatic mutation profile of tumor specimen C3L-00815-01 (aliquot CPT0085730009) from CPTAC case C3L-00815, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.9 years (28,832 days).
Specimen C3L-00815-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8ad8da5-1d4e-4641-b8c0-df31be877110.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00815-31 (Blood Derived Normal), aliquot CPT0086630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23877617-55aa-4550-9cf0-7d6508d0180a

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Frame Shift Del 6, Silent 5, Intron 4, 5'UTR 2, RNA 2, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 57/470 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376291531; called by muse, mutect2, varscan2
- CERS2 | c.520-4C>T | Splice Region (SNP) | VAF 18/155 reads (12%) | catalogued as rs765101077; called by muse, mutect2, varscan2
- FAM110A | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768615039, COSV99856695; called by muse, mutect2, varscan2
- GREB1 | c.5273G>A p.R1758Q | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760722393; called by muse, mutect2
- IDE | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs200912671; called by muse, mutect2, varscan2
- KDM5C | c.2198A>T p.H733L | Missense Mutation (SNP) | VAF 72/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64767404; called by muse, mutect2, varscan2
- MAP3K6 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs912081218, COSV100539514, COSV58871417; called by muse, mutect2, varscan2
- MET | c.3538del p.D1180Ifs*9 | Frame Shift Del (DEL) | VAF 22/172 reads (13%) | catalogued as COSV59258859; called by mutect2, pindel
- MUSK | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1403543378; called by muse, mutect2, varscan2
- SPSB3 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs892944737; called by muse, mutect2, varscan2
- USP28 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.848); catalogued as COSV50204105; called by muse, mutect2
- VHL | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as CM941366, COSV56546022, COSV56550689; called by muse, mutect2, varscan2
- XIRP2 | c.4484A>T p.E1495V (on ENST00000628543; = p.E1670V on NM_152381.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV99742206; called by muse, mutect2, varscan2
- AC090517.4 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- ATG7 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ATP5F1D | c.185C>G p.T62R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CERS6 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRACR2A | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAPK1 | c.504T>G p.I168M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND5A | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA4 | c.2857A>G p.R953G | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- FNIP2 | c.1367A>G p.D456G | Missense Mutation (SNP) | VAF 33/330 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FREM2 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FUT8 | c.441A>C p.R147S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPRASP1 | c.322del p.T108Qfs*10 | Frame Shift Del (DEL) | VAF 21/208 reads (10%) | called by mutect2, pindel*
- ITGA9 | c.2854G>T p.V952L | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MID2 | c.2017T>C p.S673P | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OPHN1 | c.53_55del p.F18_R19delinsC | In Frame Del (DEL) | VAF 26/206 reads (13%) | called by mutect2, pindel
- OR6K2 | c.305dup p.F103Lfs*8 | Frame Shift Ins (INS) | VAF 60/306 reads (20%) | called by mutect2, pindel, varscan2
- PCLO | c.9545C>A p.P3182H | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PIEZO2 | c.1671A>T p.L557F | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PPARGC1B | c.1398del p.R467Gfs*16 | Frame Shift Del (DEL) | VAF 85/381 reads (22%) | called by mutect2, pindel, varscan2
- RIMS1 | c.292del p.I98* | Frame Shift Del (DEL) | VAF 83/546 reads (15%) | called by mutect2, pindel, varscan2
- RIOX1 | c.675_681del p.E226Cfs*48 | Frame Shift Del (DEL) | VAF 28/193 reads (15%) | called by mutect2, pindel
- SAMHD1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SERGEF | c.1058_1059del p.C353Lfs*7 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- TST | c.106T>C p.W36R | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); called by muse, mutect2
- FOXO6 | c.405C>T p.A135= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- KPNA6 | c.1224A>C p.G408= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- LAMB1 | c.3636G>T p.V1212= | Silent (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- NPAT | c.2922A>T p.T974= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2640A>C p.S880= | Silent (SNP) | VAF 53/202 reads (26%) | catalogued as rs1374549038; called by muse, mutect2, varscan2
- FA2H | c.787-46C>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs983322885; called by muse, mutect2, varscan2
- LAMB1 | c.2458+49C>T | Intron (SNP) | VAF 77/307 reads (25%) | called by muse, mutect2, varscan2
- MIR1270 | n.67del | RNA (DEL) | VAF 15/143 reads (10%) | called by mutect2, pindel, varscan2
- NPY6R | n.1085T>C | RNA (SNP) | VAF 48/370 reads (13%) | called by muse, mutect2, varscan2
- PET100 | c.-12G>A | 5'UTR (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- PPA2 | c.656-6601G>C | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- SNRNP40 | c.-6G>A | 5'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- TG | c.7239+29096G>T | Intron (SNP) | VAF 38/352 reads (11%) | called by muse, mutect2, varscan2
